CCDI case PBBLSH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/233562a6-75be-43f4-99d3-4f987ace4eb9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,227 days).

Biospecimens (3 samples)
- Sample 0DCEQO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCEQU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCER1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
